Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A42C, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A42C-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT URETER, DISTAL, SHAVE MARGIN, BIOPSY-

- A. BENIGN URETER.
- B. NEGATIVE FOR NEOPLASIA.

PART 2: LEFT, URETER, DISTAL, SHAVE MARGIN, BIOPSY-

- A. BENIGN URETER.
- B. NEGATIVE FOR NEOPLASIA.

PART 3: URINARY BLADDER, DISTAL URETERS, PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL CYSTOPROSTATECTOMY -

- A. INVASIVE UROTHELIAL CARCINOMA, HIGH-GRADE (2004 WHO/ISUP) (SLIDES 3E, 3F, 3L, 3R, 3S, 3T, 3U, 3V), ASSOCIATED WITH FOCAL HIGH-GRADE PAPILLARY UROTHELIAL CARCINOMA (SLIDES 3H, 3O, 3S). TUMOR MEASURES 3.5 x 1.5 x 0.4 CM, AND IS PRESENT IN THE LEFT LATERAL WALL AND TRIGONE. CARCINOMA INFILTRATES INTO THE SUPERFICIAL DETRUSOR MUSCLE (INNER HALF).
- B. UROTHELIAL DYSPLASIA THROUGH CARCINOMA IN SITU IS PRESENT IN THE RIGHT URETERAL OSTIUM (SLIDE 3G), LEFT URETERAL OSTIUM (SLIDE 3H), AND ANTERIOR WALL / DOME (SLIDE 3N).
- C. NO DEFINITIVE ANGIOLYMPHATIC INVASION IS IDENTIFIED (SLIDE 3E).
- D. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF UROTHELIAL NEOPLASIA.
- E. TNM PATHOLOGIC STAGE: pT2a N0 MX (SEE SYNOPSIS).
- F. BACKGROUND BLADDER WITH GRANULOMATOUS INFLAMMATION (HISTORY OF BCG THERAPY) AND BIOPSY SITE CHANGES.
- G. BENIGN PROSTATE WITH MULTIFOCAL NECROTIZING GRANULOMAS (HISTORY OF BCG THERAPY), NODULAR HYPERPLASIA, FOCAL GLANDULAR ATROPHY, AND CHRONIC INFLAMMATION.
- H. BENIGN BILATERAL SEMINAL VESICLES.

PART 4: LYMPH NODES, RIGHT PELVIC, EXCISION

- A. NO EVIDENCE OF MALIGNANCY IN SEVENTEEN LYMPH NODES (0/17).
- B. ONE LYMPH NODE WITH FEW NON-NECROTIZING GRANULOMAS (SLIDE 4B).

PART 5: LYMPH NODES, LEFT PELVIC, EXCISION

- A. NO EVIDENCE OF NEOPLASIA IN SIX LYMPH NODES (0/6).
- B. ONE LYMPH NODE WITH A SMALL NON-NECROTIZING GRANULOMA (SLIDE 4K).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE: Radical cystoprostatectomy
TUMOR SITE: Trigone, Left lateral wall
TUMOR SIZE: Greatest dimension: 3.5 cm
Additional dimensions: 1.5 x 0.4 cm
HISTOLOGIC TYPE: Urothelial (transitional cell) carcinoma
ASSOCIATED EPITHELIAL LESIONS: None identified
HISTOLOGIC GRADE: Urothelial carcinoma - High-grade
TUMOR CONFIGURATION: Papillary, Flat, Ulcerated
PATHOLOGIC STAGING (pTNM): pT2a
pN0
Number of nodes examined: 23
Number of nodes involved: 0
pMX
MARGINS: Margins uninvolved by invasive carcinoma
Margin(s) uninvolved by carcinoma in situ
VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L): Absent
DIRECT EXTENSION OF INVASIVE TUMOR: None identified
ADDITIONAL PATHOLOGIC FINDINGS: Urothelial carcinoma in situ
Therapy-related changes

ICD-O-3

urothelial, carcinoma, papillary
8130/3

Sites:

path: bladder, NOS

C67.9

CQCF: bladder, wall, lateral

C67.2

9-1-12 RD

Source: NCI Genomic Data Commons file 628504c0-8db4-4d49-837f-3af9fb4e3732 (TCGA-BT-A42C.8716FEB2-A4DD-4EFF-B1A6-D679A5C75C76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).